Somatic mutation profile of tumor specimen TCGA-BS-A0V6-01A (aliquot TCGA-BS-A0V6-01A-11D-A122-09) from TCGA case TCGA-BS-A0V6, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 55.8 years (20,369 days).
Specimen TCGA-BS-A0V6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24de205b-deba-4e6a-b1ff-900a4c51a674.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BS-A0V6-10A (Blood Derived Normal), aliquot TCGA-BS-A0V6-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20792c45-0389-43ed-9a2b-a33779de6b4c

The open-access MAF lists 58 somatic variants for this specimen: 47 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 40, Silent 11, Frame Shift Del 2, Splice Site 2, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.331A>G p.K111E | Missense Mutation (SNP) | VAF 30/98 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1057519933, COSV55878486, COSV56029794; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.2816A>G p.D939G | Missense Mutation (SNP) | VAF 41/125 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.83); PolyPhen benign (0.013); catalogued as COSV55911087; called by muse, mutect2, varscan2
- PTEN | c.407G>T p.C136F | Missense Mutation (SNP) | VAF 56/276 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD110173, CM983501, COSV64288670, COSV64294671; called by muse, varscan2
- ABCA3 | c.2843C>T p.S948L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0.021); catalogued as rs561560107, COSV57060728; called by muse, mutect2, varscan2
- ADGRG4 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 79/293 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV54965380; called by muse, mutect2, varscan2
- AMDHD2 | c.1147G>A p.V383M (on ENST00000293971 / NM_001330449.2; = p.V413M on NM_015944.4) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1306197212, COSV53549555; called by muse, mutect2, varscan2
- ANO3 | c.2839C>T p.R947* | Nonsense Mutation (SNP) | VAF 51/157 reads (32%) | catalogued as rs763228921, COSV56785203; called by muse, mutect2, varscan2
- B4GALT7 | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as COSV50355776; called by muse, mutect2, varscan2
- BAHCC1 | c.1610G>A p.G537E | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as COSV57034076; called by muse, mutect2, varscan2
- BCAP31 | c.707C>A p.A236E | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.89); PolyPhen benign (0.006); catalogued as COSV53473627; called by muse, mutect2, varscan2
- BMP7 | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs1339607526, COSV67780193; called by muse, mutect2, varscan2
- CCBE1 | c.303G>T p.Q101H | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV67951730; called by muse, mutect2, varscan2
- CCDC88A | c.2768A>G p.N923S | Missense Mutation (SNP) | VAF 135/490 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.145); catalogued as rs747280965, COSV55070835; called by muse, mutect2, varscan2
- CCT7 | c.1304T>C p.I435T | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1462651875, COSV54590092; called by muse, mutect2
- CPVL | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.448); catalogued as COSV55309265; called by muse, mutect2, varscan2
- CTCF | c.1584C>A p.C528* | Nonsense Mutation (SNP) | VAF 57/198 reads (29%) | catalogued as COSV50530688; called by muse, mutect2, varscan2
- ELAC2 | c.1144A>G p.S382G | Missense Mutation (SNP) | VAF 122/450 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1490740237, COSV62034913; called by muse, mutect2, varscan2
- GABRA4 | c.865A>G p.T289A | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51935971; called by muse, mutect2, varscan2
- GPATCH8 | c.193+2T>G p.X65_splice | Splice Site (SNP) | VAF 72/308 reads (23%) | catalogued as COSV59198983; called by muse, varscan2
- GPM6A | c.571A>T p.I191F | Missense Mutation (SNP) | VAF 83/319 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV54562316; called by muse, mutect2, varscan2
- IL2 | c.331G>T p.V111L | Missense Mutation (SNP) | VAF 90/374 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs756737575, COSV56985338, COSV56986744; called by muse, mutect2, varscan2
- KAT6B | c.5020G>A p.E1674K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs1207239612, COSV54755665; called by muse, mutect2, varscan2
- KCNK9 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs774431836, COSV100271848, COSV57289066; called by muse, mutect2, varscan2
- KMT2B | c.7982C>T p.S2661F | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53076907; called by muse, mutect2, varscan2
- LACC1 | c.1269T>G p.I423M | Missense Mutation (SNP) | VAF 13/369 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.11); catalogued as COSV57829982; called by muse, mutect2
- LRRC55 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs143027441, COSV73006819; called by muse, mutect2
- MAN2A2 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1451634321, COSV64640116; called by muse, mutect2, varscan2
- MAT2B | c.645C>G p.H215Q | Missense Mutation (SNP) | VAF 65/183 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as COSV55202570; called by muse, mutect2, varscan2
- MMS22L | c.2537-1G>A p.X846_splice | Splice Site (SNP) | VAF 63/183 reads (34%) | catalogued as COSV51527301; called by muse, mutect2, varscan2
- NUSAP1 | c.330A>G p.I110M | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV52973779; called by muse, mutect2, varscan2
- OR10G9 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 123/385 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66686932; called by muse, mutect2, varscan2
- OR4A15 | c.684G>C p.L228F | Missense Mutation (SNP) | VAF 140/453 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.03); catalogued as COSV100124304, COSV59038052; called by muse, mutect2, varscan2
- PARP3 | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as COSV51757071; called by muse, mutect2, varscan2
- PER1 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771047267, COSV57921648; called by muse, mutect2, varscan2
- PLPPR4 | c.238T>C p.S80P | Missense Mutation (SNP) | VAF 63/237 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV64571204; called by muse, mutect2, varscan2
- PSG11 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 180/351 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60458287; called by muse, mutect2, varscan2
- RAP1GAP2 | c.322C>A p.Q108K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV54590046; called by muse, mutect2, varscan2
- RHEB | c.70A>G p.I24V | Missense Mutation (SNP) | VAF 15/344 reads (4%) | SIFT tolerated (0.99); PolyPhen possibly damaging (0.65); catalogued as COSV51264747; called by muse, mutect2
- RNASEL | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs747178598, COSV62376202; called by muse, mutect2, varscan2
- SFR1 | c.232G>A p.E78K (on ENST00000369727 / NM_001002759.1; = p.E65K on NM_145247.4) | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV60479981; called by muse, mutect2
- ST8SIA4 | c.58T>C p.Y20H | Missense Mutation (SNP) | VAF 12/299 reads (4%) | PolyPhen probably damaging (0.969); catalogued as COSV51517423; called by muse, mutect2
- TCEAL6 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 84/344 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV65654311; called by muse, mutect2, varscan2
- TINAG | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 12/388 reads (3%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV52511008, COSV52515989; called by muse, mutect2
- TMEM150A | c.316C>T p.R106W (on ENST00000334462 / NM_001031738.3; = p.R53W on NM_153342.3) | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs768122080, COSV57818793; called by muse, mutect2, varscan2
- ARID1A | c.6757_6758del p.L2253Vfs*24 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | called by pindel, varscan2
- ARID1A | c.6764_6770del p.E2255Gfs*10 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by pindel, varscan2
- IHH | c.824_831dup p.F278Tfs*90 | Frame Shift Ins (INS) | VAF 14/48 reads (29%) | called by mutect2, varscan2
- BEST3 | c.792C>T p.Y264= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as rs780570896, COSV58306312; called by muse, mutect2, varscan2
- CDK5R1 | c.795C>T p.I265= | Silent (SNP) | VAF 54/139 reads (39%) | catalogued as COSV57831949; called by muse, mutect2, varscan2
- CNTN4 | c.1659A>T p.G553= | Silent (SNP) | VAF 78/247 reads (32%) | catalogued as COSV61881862; called by muse, mutect2, varscan2
- GCNT4 | c.117G>A p.P39= | Silent (SNP) | VAF 36/123 reads (29%) | catalogued as rs147043874, COSV59280873; called by muse, mutect2, varscan2
- GLB1L3 | c.450C>T p.A150= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as rs770897644, COSV66283668; called by muse, mutect2, varscan2
- MAP7D3 | c.2508C>G p.T836= | Silent (SNP) | VAF 156/556 reads (28%) | catalogued as COSV60172797; called by muse, mutect2, varscan2
- MUC5B | c.13593C>A p.G4531= | Silent (SNP) | VAF 75/407 reads (18%) | catalogued as COSV71595983; called by muse, mutect2, varscan2
- SBF2 | c.2598G>A p.P866= | Silent (SNP) | VAF 67/220 reads (30%) | catalogued as rs376372877, COSV56313084; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TNFAIP1 | c.678C>T p.T226= | Silent (SNP) | VAF 10/164 reads (6%) | catalogued as COSV50229024; called by muse, mutect2
- TOPBP1 | c.2868G>A p.R956= | Silent (SNP) | VAF 69/285 reads (24%) | catalogued as COSV53442618; called by muse, mutect2, varscan2
- TOX2 | c.459G>A p.S153= (on ENST00000358131 / NM_001098798.2; = p.S102= on NM_032883.3) | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs755207008, COSV57886076, COSV57896735; called by muse, mutect2, varscan2
